Somatic mutation profile of tumor specimen ALCH-B2M5-TTP1-A (aliquot ALCH-B2M5-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2M5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.9 years (25,529 days).
Specimen ALCH-B2M5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0030af95-0cfa-409e-bf5e-4abea22325c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2M5-NB1-A (Blood Derived Normal), aliquot ALCH-B2M5-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69c07616-3b72-48c8-ba87-a61280c5d471

The open-access MAF lists 258 somatic variants for this specimen: 161 protein-altering or splice-affecting, 55 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 55, Intron 17, Nonsense Mutation 9, Frame Shift Del 8, RNA 8, 5'UTR 7, 3'UTR 5, 5'Flank 3, 3'Flank 2, In Frame Del 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1176G>T p.L392F | Missense Mutation (SNP) | VAF 84/399 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55948254; called by muse, mutect2, varscan2
- ADK | c.944C>T p.A315V (on ENST00000286621; = p.A298V on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as CM162754; called by muse, mutect2, varscan2
- AKR1B1 | c.429G>A p.A143= | Splice Region (SNP) | VAF 187/361 reads (52%) | catalogued as rs567808791; called by muse, varscan2
- ARHGEF7 | c.1888G>T p.G630C (on ENST00000375741 / NM_001113511.2; = p.G452C on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 196/489 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99522327; called by muse, mutect2, varscan2
- ATP4A | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762433608; called by muse, mutect2, varscan2
- ATP5F1C | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs767576694; called by muse, mutect2, varscan2
- BAHCC1 | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370302611; called by muse, mutect2, varscan2
- C10orf71 | c.4165C>A p.H1389N | Missense Mutation (SNP) | VAF 344/882 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1418949688; called by muse, mutect2, varscan2
- CATSPERE | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs573295079; called by muse, mutect2, varscan2
- CFHR5 | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 162/296 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99889531; called by muse, mutect2, varscan2
- CLIP2 | c.2873C>G p.T958S | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.031); catalogued as COSV56281184; called by muse, mutect2, varscan2
- COQ8A | c.1256G>T p.R419M | Missense Mutation (SNP) | VAF 414/808 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs546015164; called by muse, mutect2, varscan2
- CYTL1 | c.230T>C p.F77S | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs761212866; called by muse, mutect2, varscan2
- DCHS2 | c.1434C>A p.F478L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59720604; called by muse, mutect2, varscan2
- DNAH12 | c.9230G>T p.R3077L (on ENST00000351747; = p.R3945L on NM_001366028.2) | Missense Mutation (SNP) | VAF 115/314 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs914537394; called by muse, mutect2, varscan2
- DNMT3B | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 180/508 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as COSV52415517; called by muse, mutect2, varscan2
- ELAVL2 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 110/243 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs1270239548, COSV56368718, COSV99807403; called by muse, mutect2, varscan2
- FERD3L | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 177/558 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51764762, COSV99284751; called by muse, mutect2, varscan2
- GAB4 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 94/249 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV68755274; called by muse, mutect2, varscan2
- GFM1 | c.1877T>A p.F626Y | Missense Mutation (SNP) | VAF 85/370 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1051869589; called by muse, mutect2, varscan2
- GP6 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 137/833 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344152418, COSV59979720; called by muse, mutect2, varscan2
- H4C6 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as rs1325766746; called by muse, mutect2, varscan2
- HCN1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV100299758; called by muse, varscan2
- HECTD3 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64670913; called by muse, mutect2, varscan2
- ID3 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs748225151; called by muse, mutect2, varscan2
- IGFN1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1224393502; called by muse, mutect2, varscan2
- INSRR | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs754589437, COSV63876113; called by muse, mutect2, varscan2
- KAZALD1 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV64630131; called by muse, mutect2
- KCNA3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1049290141; called by muse, mutect2, varscan2
- KCNH2 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs866464373, COSV51216390; called by muse, mutect2, varscan2
- KIRREL1 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 89/371 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV63288206; called by muse, mutect2, varscan2
- KMT2C | c.12307G>A p.D4103N | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1221667616; called by muse, mutect2, varscan2
- LAMA4 | c.1403G>A p.R468H (on ENST00000230538 / NM_001105206.3; = p.R461H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/458 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1554342373; called by muse, mutect2, varscan2
- LATS2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 68/389 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs113238499, COSV66873645, COSV66876566; called by muse, mutect2, varscan2
- LMBRD2 | c.1961A>C p.D654A | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as COSV99682480; called by muse, mutect2, varscan2
- LONRF2 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs569402017; called by muse, mutect2, varscan2
- MAGEC1 | c.2425C>A p.P809T | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.253); catalogued as COSV53567235; called by muse, mutect2, varscan2
- MAGEC1 | c.2426C>A p.P809H | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV99596996; called by muse, mutect2, varscan2
- MUC16 | c.39386C>A p.T13129N | Missense Mutation (SNP) | VAF 107/415 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.958); catalogued as COSV66691898; called by muse, mutect2, varscan2
- NALCN | c.3777G>C p.K1259N | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99214198; called by muse, mutect2, varscan2
- NANOGNB | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.074); catalogued as rs1363620658, COSV66125185; called by muse, mutect2
- NEGR1 | c.858C>G p.N286K | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60833582; called by muse, mutect2, varscan2
- NR1H2 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772741012; called by muse, mutect2, varscan2
- NUP155 | c.274G>A p.E92K (on ENST00000231498 / NM_153485.3; = p.E33K on NM_004298.4) | Missense Mutation (SNP) | VAF 129/495 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51534970; called by muse, mutect2, varscan2
- NYAP2 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56005570, COSV56011602; called by muse, mutect2, varscan2
- OOSP2 | c.347+1G>T p.X116_splice | Splice Site (SNP) | VAF 39/111 reads (35%) | catalogued as COSV53929501, COSV99613696; called by muse, mutect2, varscan2
- OR2M2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 116/799 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs150685608; called by muse, mutect2, varscan2
- OR5M8 | c.665C>A p.P222H | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.617); catalogued as COSV59115639; called by muse, mutect2, varscan2
- PCYT1B | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63265706; called by muse, mutect2, varscan2
- PKD1L1 | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 115/678 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221513; called by muse, mutect2, varscan2
- POU6F2 | c.1442T>A p.L481Q | Missense Mutation (SNP) | VAF 102/555 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68876301; called by muse, mutect2, varscan2
- PRKCI | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs775812965, COSV99856257; called by muse, mutect2, varscan2
- PRRC2C | c.8210G>T p.R2737I (on ENST00000367742; = p.R2735I on NM_015172.4) | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV58910207; called by muse, mutect2, varscan2
- PRSS38 | c.641G>T p.C214F | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361375249; called by muse, mutect2, varscan2
- PZP | c.826A>T p.N276Y | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs749639362; called by muse, mutect2, varscan2
- RDH12 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 50/772 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767385752, COSV50821901; called by muse, mutect2
- ROS1 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426748283; called by muse, mutect2, varscan2
- SCART1 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 85/380 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.171); catalogued as rs906998877, COSV62988661; called by muse, mutect2, varscan2
- SH3RF1 | c.2420C>G p.P807R | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99498912; called by muse, mutect2, varscan2
- SIM1 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as CM139639, COSV53490504, COSV53495240; called by muse, mutect2, varscan2
- SIM1 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53493311; called by muse, mutect2, varscan2
- SKI | c.1254C>A p.N418K | Missense Mutation (SNP) | VAF 319/610 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66013509; called by muse, mutect2, varscan2
- SLC25A20 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 218/510 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs138433512; called by muse, mutect2, varscan2
- SLC44A5 | c.1262C>A p.P421Q | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100901191; called by muse, varscan2
- SLC44A5 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63762747; called by muse, varscan2
- SNRNP70 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 389/900 reads (43%) | catalogued as rs940780487, COSV55505482; called by muse, mutect2, varscan2
- SPCS2 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV55228682; called by muse, mutect2, varscan2
- TFAP2A | c.974G>A p.R325Q (on ENST00000482890; = p.R317Q on NM_001032280.3) | Missense Mutation (SNP) | VAF 100/747 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60234808; called by muse, mutect2, varscan2
- TMEM30A | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs1283188024, COSV57874936; called by muse, mutect2, varscan2
- TNS3 | c.3298G>C p.E1100Q | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100236536; called by muse, mutect2, varscan2
- TTN | c.97442G>T p.G32481V (on ENST00000591111; = p.G25057V on NM_003319.4) | Missense Mutation (SNP) | VAF 89/338 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV60409949; called by muse, mutect2, varscan2
- UBTD1 | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs142013910; called by muse, mutect2, varscan2
- AGAP2 | c.17del p.G6Afs*14 | Frame Shift Del (DEL) | VAF 121/462 reads (26%) | called by mutect2, pindel, varscan2
- ALOX12B | c.1127G>T p.W376L | Missense Mutation (SNP) | VAF 274/475 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- ARCN1 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 46/275 reads (17%) | called by muse, mutect2, varscan2
- ASIC3 | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC141 | c.4240C>T p.L1414F | Missense Mutation (SNP) | VAF 76/439 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CHRNA1 | c.1083del p.F361Lfs*14 (on ENST00000261007 / NM_001039523.3; = p.F336Lfs*14 on NM_000079.4) | Frame Shift Del (DEL) | VAF 60/302 reads (20%) | called by pindel, varscan2
- CSMD1 | c.4249C>T p.Q1417* (on ENST00000520002; = p.Q1416* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 99/304 reads (33%) | called by muse, mutect2, varscan2
- CYP2S1 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYRIB | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DMBT1 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 107/418 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DOCK9 | c.5091G>A p.M1697I (on ENST00000376460 / NM_001366676.2; = p.M1698I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DOK7 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by mutect2, varscan2
- EEF2K | c.1618T>A p.C540S | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ENOX2 | c.1164G>T p.M388I (on ENST00000338144 / NM_001382520.1; = p.M359I on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ENTPD4 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ENY2 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERICH3 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FARS2 | c.15_29del p.L6_A10del | In Frame Del (DEL) | VAF 45/190 reads (24%) | called by mutect2, pindel, varscan2
- FBXW7 | c.2042del p.K681Sfs*26 (on ENST00000281708 / NM_001349798.2; = p.K601Sfs*26 on NM_018315.5) | Frame Shift Del (DEL) | VAF 97/557 reads (17%) | called by mutect2, pindel, varscan2
- FGD6 | c.4012_4021del p.G1338Tfs*17 | Frame Shift Del (DEL) | VAF 29/258 reads (11%) | called by mutect2, pindel, varscan2
- FKBP15 | c.2057A>T p.Q686L | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- FLG | c.2943del p.S982Pfs*140 | Frame Shift Del (DEL) | VAF 106/904 reads (12%) | called by mutect2, varscan2
- FLG | c.2942G>T p.G981V | Missense Mutation (SNP) | VAF 109/906 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by mutect2, varscan2
- FZD1 | c.1896G>C p.K632N | Missense Mutation (SNP) | VAF 107/455 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GAP43 | c.422A>T p.E141V | Missense Mutation (SNP) | VAF 91/154 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KCNB2 | c.2667G>T p.L889F | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.701); called by muse, varscan2
- KCNV2 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 167/363 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KIAA1671 | c.2245T>G p.S749A | Missense Mutation (SNP) | VAF 213/526 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF21A | c.716T>G p.V239G | Missense Mutation (SNP) | VAF 326/757 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- KRTAP10-1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 532/2129 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- LRRC7 | c.1118del p.P373Qfs*13 (on ENST00000651989 / NM_001370785.2; = p.P340Qfs*13 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/239 reads (41%) | called by mutect2, pindel, varscan2
- LRRK2 | c.1422C>A p.N474K | Missense Mutation (SNP) | VAF 245/1778 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LTN1 | c.1853C>G p.S618C | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LY75 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 128/332 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MLIP | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, varscan2
- MRPL24 | c.69G>T p.M23I | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MTIF2 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 218/361 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- MUC16 | c.39422G>A p.W13141* | Nonsense Mutation (SNP) | VAF 139/466 reads (30%) | called by muse, mutect2, varscan2
- MUC16 | c.3913C>A p.P1305T | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NOMO3 | c.1698G>C p.W566C | Missense Mutation (SNP) | VAF 118/701 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- NPR1 | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 200/297 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR10Z1 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 155/503 reads (31%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR4F6 | c.36del p.F12Lfs*28 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- PCDHGA5 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 243/481 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB3 | c.1592C>A p.T531N | Missense Mutation (SNP) | VAF 457/873 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PCLO | c.13411A>G p.R4471G | Missense Mutation (SNP) | VAF 226/473 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PLXNA2 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- POLR3B | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 148/344 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.216); called by muse, varscan2
- POLR3E | c.308_312del p.C103Ffs*6 | Frame Shift Del (DEL) | VAF 42/238 reads (18%) | called by mutect2, pindel, varscan2
- PRAM1 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 200/605 reads (33%) | called by muse, mutect2, varscan2
- PSD4 | c.2498G>C p.G833A | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- PTPRE | c.1464+5G>C | Splice Region (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- RC3H2 | c.834A>T p.R278S | Missense Mutation (SNP) | VAF 169/708 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RC3H2 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 172/706 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RIC3 | c.427+1G>A p.X143_splice | Splice Site (SNP) | VAF 139/279 reads (50%) | called by muse, mutect2, varscan2
- RIPK3 | c.251G>A p.W84* | Nonsense Mutation (SNP) | VAF 79/437 reads (18%) | called by muse, mutect2, varscan2
- RNASE8 | c.74T>A p.V25D | Missense Mutation (SNP) | VAF 62/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RP1L1 | c.6986A>T p.K2329M | Missense Mutation (SNP) | VAF 222/587 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- RSPO3 | c.53A>T p.Y18F | Missense Mutation (SNP) | VAF 58/424 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPO4 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 48/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAE1 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 152/374 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SALL1 | c.925A>G p.S309G | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, varscan2
- SERPINC1 | c.692C>G p.T231S | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIPA1L1 | c.4936G>A p.A1646T | Missense Mutation (SNP) | VAF 124/252 reads (49%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SLC16A11 | c.611C>A p.T204N (on ENST00000308009; = p.T180N on NM_153357.3) | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- SLIT2 | c.4123T>A p.C1375S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPANXN3 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 107/173 reads (62%) | SIFT tolerated (0.45); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- STARD8 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 42/63 reads (67%) | called by muse, mutect2, varscan2
- STAU2 | c.399G>T p.M133I (on ENST00000524300 / NM_001164380.2; = p.M101I on NM_014393.2) | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TAOK3 | c.2670A>C p.L890F | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TAS2R31 | c.504G>T p.L168F | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TECTA | c.2649G>C p.E883D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TEX13C | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 144/257 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- TMEM161A | c.108_116del p.S36_F38del | In Frame Del (DEL) | VAF 30/300 reads (10%) | called by mutect2, pindel
- TMX3 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 78/432 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.908); called by muse, varscan2
- TP53 | c.481_483dup p.A161dup | In Frame Ins (INS) | VAF 164/318 reads (52%) | called by mutect2, pindel, varscan2
- TRDN | c.2101G>T p.G701* | Nonsense Mutation (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- TTC30A | c.206A>T p.E69V | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- UBXN2B | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UGT2B4 | c.67T>A p.C23S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, varscan2
- UNC80 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 235/815 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UNC80 | c.2827G>T p.G943W | Missense Mutation (SNP) | VAF 154/562 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VAV3 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 84/169 reads (50%) | called by muse, mutect2, varscan2
- WDR17 | c.620A>T p.N207I | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2
- ZFHX4 | c.7124A>G p.N2375S | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF334 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF562 | c.887C>T p.S296F (on ENST00000453372 / NM_001130032.2; = p.S224F on NM_017656.4) | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ZZEF1 | c.2992G>A p.V998M | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ABCD2 | c.1164C>G p.A388= | Silent (SNP) | VAF 399/904 reads (44%) | called by muse, mutect2, varscan2
- ADGRB3 | c.1530T>A p.P510= | Silent (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- ASB5 | c.966G>A p.L322= | Silent (SNP) | VAF 65/319 reads (20%) | called by muse, mutect2, varscan2
- BMP5 | c.936T>A p.L312= | Silent (SNP) | VAF 125/676 reads (18%) | called by muse, mutect2, varscan2
- C8orf34 | c.588A>G p.P196= | Silent (SNP) | VAF 30/256 reads (12%) | called by muse, mutect2, varscan2
- CADM1 | c.1104G>A p.S368= | Silent (SNP) | VAF 204/495 reads (41%) | catalogued as rs552336980, COSV59009621; called by muse, mutect2, varscan2
- CD101 | c.2604T>C p.D868= | Silent (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- CHAT | c.192G>T p.A64= | Silent (SNP) | VAF 183/367 reads (50%) | called by muse, mutect2, varscan2
- CNGA3 | c.762G>A p.L254= | Silent (SNP) | VAF 79/264 reads (30%) | called by muse, mutect2, varscan2
- CUZD1 | c.672G>A p.L224= | Silent (SNP) | VAF 53/261 reads (20%) | catalogued as COSV59026125; called by muse, mutect2, varscan2
- FSIP2 | c.4536C>T p.I1512= | Silent (SNP) | VAF 30/280 reads (11%) | catalogued as rs1468927628, COSV100556492; called by muse, mutect2, varscan2
- GAB4 | c.270C>T p.P90= | Silent (SNP) | VAF 93/247 reads (38%) | catalogued as COSV101271912; called by muse, mutect2, varscan2
- GLB1L3 | c.1956G>C p.T652= | Silent (SNP) | VAF 91/240 reads (38%) | called by muse, mutect2, varscan2
- GMDS | c.915A>G p.E305= | Silent (SNP) | VAF 122/438 reads (28%) | called by muse, mutect2, varscan2
- GPR155 | c.639T>G p.R213= | Silent (SNP) | VAF 105/308 reads (34%) | called by muse, mutect2, varscan2
- GRIA4 | c.1980C>T p.D660= | Silent (SNP) | VAF 149/390 reads (38%) | called by muse, mutect2, varscan2
- GRIK3 | c.2178C>A p.I726= | Silent (SNP) | VAF 197/423 reads (47%) | called by muse, mutect2, varscan2
- IGSF11 | c.159T>C p.I53= (on ENST00000393775 / NM_001015887.3; = p.I52= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 171/318 reads (54%) | called by muse, mutect2, varscan2
- LACTBL1 | c.120C>A p.A40= (on ENST00000618559; = p.A69= on NM_001289974.2) | Silent (SNP) | VAF 124/297 reads (42%) | called by muse, mutect2, varscan2
- LAMA5 | c.3654C>T p.A1218= | Silent (SNP) | VAF 26/634 reads (4%) | catalogued as rs923938546, COSV53367377; called by muse, mutect2
- LRRK2 | c.579G>A p.E193= | Silent (SNP) | VAF 30/732 reads (4%) | catalogued as COSV54157750; called by muse, mutect2
- MMP16 | c.663T>C p.H221= | Silent (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- MROH6 | c.1425G>C p.V475= | Silent (SNP) | VAF 150/366 reads (41%) | called by muse, varscan2
- MTUS2 | c.9C>T p.V3= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV101462290; called by mutect2, varscan2
- MYOF | c.5685G>T p.L1895= | Silent (SNP) | VAF 49/206 reads (24%) | called by muse, varscan2
- NAF1 | c.864A>T p.T288= | Silent (SNP) | VAF 18/80 reads (23%) | called by muse, varscan2
- NEK2 | c.1269G>T p.R423= | Silent (SNP) | VAF 233/713 reads (33%) | called by muse, mutect2, varscan2
- NFE2L2 | c.786C>T p.D262= | Silent (SNP) | VAF 104/347 reads (30%) | catalogued as COSV101229308; called by muse, mutect2, varscan2
- OR4K2 | c.666G>T p.L222= | Silent (SNP) | VAF 116/1267 reads (9%) | called by muse, mutect2
- OR5J2 | c.756T>C p.Y252= | Silent (SNP) | VAF 69/234 reads (29%) | called by muse, mutect2, varscan2
- PFKFB4 | c.282C>T p.P94= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as rs138881496; called by muse, mutect2, varscan2
- PKP3 | c.615G>A p.A205= | Silent (SNP) | VAF 185/340 reads (54%) | catalogued as rs751556651; called by muse, mutect2, varscan2
- PODN | c.1134C>A p.T378= (on ENST00000395871; = p.T330= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 240/550 reads (44%) | catalogued as rs1557655937, COSV57014785; called by muse, mutect2, varscan2
- PRMT9 | c.2457C>A p.P819= | Silent (SNP) | VAF 70/374 reads (19%) | called by mutect2, varscan2
- PRPH | c.1008G>A p.L336= | Silent (SNP) | VAF 331/1105 reads (30%) | called by muse, mutect2, varscan2
- PTPRK | c.2874C>A p.T958= (on ENST00000368215 / NM_001291984.2; = p.T959= on NM_002844.4) | Silent (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- RAG2 | c.648C>A p.I216= | Silent (SNP) | VAF 177/562 reads (31%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1320C>T p.V440= | Silent (SNP) | VAF 145/423 reads (34%) | catalogued as rs144728511; called by muse, varscan2
- RXFP4 | c.1113G>A p.G371= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100563506; called by muse, mutect2
- SLC11A1 | c.57C>T p.S19= | Silent (SNP) | VAF 181/418 reads (43%) | catalogued as rs777647702, COSV99262240; called by muse, mutect2, varscan2
- SLC12A9 | c.661T>C p.L221= | Silent (SNP) | VAF 265/448 reads (59%) | called by muse, mutect2, varscan2
- SLC9A2 | c.2289A>G p.L763= | Silent (SNP) | VAF 98/410 reads (24%) | catalogued as rs1261491557; called by muse, mutect2, varscan2
- SOGA1 | c.2256G>A p.L752= | Silent (SNP) | VAF 59/168 reads (35%) | catalogued as rs540498791; called by muse, mutect2, varscan2
- SPIDR | c.939A>G p.Q313= | Silent (SNP) | VAF 139/480 reads (29%) | catalogued as rs782675323; called by muse, mutect2, varscan2
- SUMF1 | c.141G>T p.A47= | Silent (SNP) | VAF 193/333 reads (58%) | called by muse, mutect2, varscan2
- TBX3 | c.1860C>A p.S620= (on ENST00000257566 / NM_016569.4; = p.S600= on NM_005996.4) | Silent (SNP) | VAF 102/207 reads (49%) | called by muse, mutect2, varscan2
- THAP12 | c.1468C>T p.L490= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- TINAG | c.582T>A p.T194= | Silent (SNP) | VAF 42/262 reads (16%) | called by muse, mutect2, varscan2
- TMEM200A | c.1134C>G p.A378= | Silent (SNP) | VAF 135/427 reads (32%) | catalogued as COSV51655420; called by muse, mutect2, varscan2
- TOX2 | c.1452G>T p.S484= (on ENST00000358131 / NM_001098798.2; = p.S460= on NM_032883.3) | Silent (SNP) | VAF 80/199 reads (40%) | catalogued as rs754898188, COSV57893505; called by muse, mutect2, varscan2
- VIPAS39 | c.987C>T p.L329= | Silent (SNP) | VAF 230/517 reads (44%) | called by muse, mutect2, varscan2
- ZFAND4 | c.432A>G p.V144= | Silent (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- ZFP91 | c.150G>A p.L50= | Silent (SNP) | VAF 97/242 reads (40%) | called by muse, mutect2, varscan2
- ZNF341 | c.807G>A p.Q269= | Silent (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- ZNF607 | c.1554A>G p.G518= | Silent (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- AC099654.5 | n.138G>A | RNA (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- AC104472.1 | n.288T>C | RNA (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- AC243919.1 | n.390C>T | RNA (SNP) | VAF 208/875 reads (24%) | catalogued as rs1065744; called by mutect2, varscan2
- ADORA1 | c.342-14592A>T | Intron (SNP) | VAF 103/179 reads (58%) | called by muse, mutect2, varscan2
- AGGF1 | c.-217C>T | 5'UTR (SNP) | VAF 115/412 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*3847G>A | 3'UTR (SNP) | VAF 12/58 reads (21%) | catalogued as rs764794139; called by muse, mutect2
- ARID3B | c.*1738T>C | 3'UTR (SNP) | VAF 34/395 reads (9%) | catalogued as rs1349885380; called by mutect2, varscan2
- BRF1 | c.*1024C>T | 3'UTR (SNP) | VAF 355/758 reads (47%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967698 G>A | 3'Flank (SNP) | VAF 157/388 reads (40%) | catalogued as rs781931981, COSV100524099; called by muse, mutect2, varscan2
- CCDC191 | c.-24G>A | 5'UTR (SNP) | VAF 357/793 reads (45%) | called by muse, mutect2, varscan2
- CMAHP | n.1073A>C | RNA (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- COL4A3 | c.325-25T>G | Intron (SNP) | VAF 83/894 reads (9%) | called by muse, mutect2
- DHX38 | c.*252G>T | 3'UTR (SNP) | VAF 68/327 reads (21%) | called by muse, mutect2, varscan2
- GUSBP1 | n.89G>C | RNA (SNP) | VAF 71/648 reads (11%) | called by muse, mutect2, varscan2
- IL15RA | c.693-89G>A | Intron (SNP) | VAF 81/462 reads (18%) | called by muse, mutect2, varscan2
- IMMP2L | c.239+94411G>T | Intron (SNP) | VAF 109/224 reads (49%) | catalogued as rs754696813; called by muse, mutect2, varscan2
- JMJD1C | c.-37A>G | 5'UTR (SNP) | VAF 69/307 reads (22%) | called by muse, mutect2, varscan2
- KCTD2 | chr17:75047193 C>T | 5'Flank (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2
- KMT5C | c.570+774A>T | Intron (SNP) | VAF 169/408 reads (41%) | called by muse, mutect2, varscan2
- LDLR | c.313+45G>T | Intron (SNP) | VAF 168/514 reads (33%) | called by mutect2, varscan2
- MAP7D1 | c.-27C>A | 5'UTR (SNP) | VAF 307/558 reads (55%) | called by muse, varscan2
- MAPK3 | c.1017+34G>T | Intron (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- MSC | c.-80G>T | 5'UTR (SNP) | VAF 82/265 reads (31%) | catalogued as rs960005936; called by muse, mutect2, varscan2
- MUC19 | chr12:40563560 G>A | 5'Flank (SNP) | VAF 100/901 reads (11%) | called by muse, mutect2, varscan2
- NDEL1 | c.-96G>A | 5'UTR (SNP) | VAF 102/312 reads (33%) | catalogued as rs756086784; called by muse, varscan2
- NPIPB10P | n.926T>C | RNA (SNP) | VAF 149/1619 reads (9%) | called by muse, varscan2
- OBSCN | c.18662-2814G>A | Intron (SNP) | VAF 42/252 reads (17%) | catalogued as rs370692094; called by muse, mutect2, varscan2
- PARGP1 | n.1176A>C | RNA (SNP) | VAF 39/379 reads (10%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-21062C>T | Intron (SNP) | VAF 36/218 reads (17%) | catalogued as rs759976203, COSV66883518; called by muse, mutect2, varscan2
- POLA1 | c.2947-20962A>G | Intron (SNP) | VAF 32/329 reads (10%) | catalogued as rs267606425, COSV66883533; called by muse, mutect2, varscan2
- RALYL | c.-24+568C>A | Intron (SNP) | VAF 245/879 reads (28%) | called by muse, mutect2, varscan2
- RIC8B | c.84+41G>T | Intron (SNP) | VAF 54/86 reads (63%) | catalogued as rs1311030407; called by muse, mutect2, varscan2
- RNF213 | c.261+5477G>T | Intron (SNP) | VAF 122/252 reads (48%) | called by muse, mutect2, varscan2
- RO60 | chr1:193085000 T>C | 3'Flank (SNP) | VAF 22/40 reads (55%) | called by muse, varscan2
- RUFY1 | c.311-4322C>T | Intron (SNP) | VAF 48/316 reads (15%) | catalogued as rs1490417949; called by muse, varscan2
- SERPINH1 | c.*39A>G | 3'UTR (SNP) | VAF 112/505 reads (22%) | called by muse, mutect2, varscan2
- SLC6A8 | c.778-162C>T | Intron (SNP) | VAF 53/67 reads (79%) | catalogued as rs782132190; called by muse, mutect2, varscan2
- TOPAZ1 | c.-56C>T | 5'UTR (SNP) | VAF 10/229 reads (4%) | catalogued as COSV100555263; called by muse, mutect2
- U2AF1L4 | c.578+182G>C | Intron (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- UBTFL2 | n.734T>G | RNA (SNP) | VAF 211/847 reads (25%) | called by muse, mutect2, varscan2
- USB1 | c.449+970_449+1012del | Intron (DEL) | VAF 76/361 reads (21%) | called by mutect2, pindel
- ZNF578 | chr19:52451343 C>T | 5'Flank (SNP) | VAF 386/796 reads (48%) | catalogued as COSV99990435; called by muse, mutect2, varscan2
